Surgical pathology report (de-identified scan), TCGA case TCGA-D8-A1XQ, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site Greater Poland Cancer Center, specimen TCGA-D8-A1XQ-01A (Primary Tumor).

Department of Cancer Pathology

copy No.

Date:

Examination: Histopathological examination

Internal invoice No.

Cost of diagnostic procedure

Examination No.:

Patient: XXX

PESEL: XXX

Age: Gender: F

10D-0-3

Material: Multiple organ resection – right breast with axillary tissues

Unit in charge:

carcinoma, infiltrating duct, nos 8500/
Site: breast, nos C50.9 in 4/12/11

Physician in charge:

Material collected on:

Material received on:

Expected time of examination: up to 8 working days

Clinical diagnosis: Cancer of the right breast. Specimen from a modified radical mastectomy using technique.

Examination performed on:

Macroscopic description:

Right breast sized 20 x 16 x 5 cm removed along with axillary tissues sized 9 x 11 x 3 cm and a skin flap of 20 x 8 cm. Weight 880 g.

Tumour sized 2.2 x 2.0 x 1.5 cm on the border of the outer quadrants, located 3.0 cm from the lower boundary, 1.2 cm from the base and 1.6 cm from the skin. Lymph nodes of 1.0 cm in length.

Microscopic description:

Carcinoma ductale invasivum, basal-like NHG3 (3 + 3 + 2/15 mitoses/10 HPF - visual area 0.55 mm).

Reactio lymphocytaria peritumoralls.

Mamilla sine laesionibus.

Axillary lymph nodes:

Lymphonodulitis reactiva No VII.

Histopathological diagnosis:

Invasive ductal carcinoma of the right breast (NHG3, pT2, pNO).

Compliance validated by:

Examination performed on:

Results of immunohistochemical examination:

No estrogen receptors found in neoplastic cell nuclei. Progesterone receptors found in less than 10% of neoplastic cell nuclei. HER2 protein stained with HercepTest™ by DAKO. Negative reaction in invasive cancerous cells (Score = 1+). Tests performed twice.

Compliance vali

CONTACT YOUR DOCTOR WITH THIS REPORT

Source: NCI Genomic Data Commons file 1bc3b6c4-6ce9-4b6f-ae85-2cd8adad616f (TCGA-D8-A1XQ.33B6269D-1D59-4184-A786-2BEB73F6D3A8.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).